TARGET case TARGET-50-PAJLXI — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4f8a9708-57f2-5971-83e3-929b9c4f21b8

Demographics
Sex at birth: male; Race: white; Age at index: 9 years; Vital status: Alive.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 9.6 years (3,514 days); Year of diagnosis: 1997; Days to last follow up: 2,293 days (6.3 years); Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, no distant metastasis; Wilms tumor histologic subtype: Favorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (1 entry)
- Days to follow up: 2,293 days (6.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,293; Year of follow up: 2003.

Biospecimens (1 sample)
- Sample TARGET-50-PAJLXI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2293
- Stage: III
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: FHWT
